Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2MS, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2MS-06A (Metastatic).

DOB/Age/Sex:

Location:

Requested by:

Requested on:

Specimen Rcvd:

Accession No.:

Copies to:

HISTOPATHOLOGY REPORT

REFERRED MRN

CLINICAL DETAILS

Mass in right axilla. PH of melanoma. (FNAB +ve). Ref: . Right axilla contents. Portion of mass removed for . Taken for tumour bank. *Only formalin sent to RPA x 1.

MACROSCOPIC DESCRIPTION

(D:

"CONTENTS RIGHT AXILLA". A piece of fat with attached muscle, the fat measures 180 x 110 x 40mm and the muscle measures 80 x 80 x 25mm. The tissue dissected from the muscle into opposite ends. Within the fat there are multiple lymph nodes, variable in size from 1mm up to 35 x 25 x 20mm. The cut surface of the largest lymph node appears necrotic and nodular.

- A. 4 lymph nodes.
- B. 4 lymph nodes.
- C. 4 lymph nodes.
- D. 3 lymph nodes.
- E. 3 lymph nodes.
- F. 1 section of largest lymph node.
- G. 2 lymph nodes.
- H. 3 lymph nodes.
- J. 1 lymph node bisected.
- K. 2 lymph nodes.
- L. 2 lymph nodes.
- M. 1 lymph node.
- N. 1 lymph node bisected.
- P. 1 lymph node bisected.
- Q. One section of second largest lymph node.
- R. One section of third largest lymph node.
- S. One lymph node bisected.

1CD-0-3

Melanoma, NOS 8720/3

Site: lymph node, axilla C77.3

/w 8/24/11

Case is (c) (4)		
	W 8/24/11	

MICROSCOPIC REPORT

A total of 33 lymph nodes were examined. Only one lymph node was found to contain metastatic melanoma, (35mm in size). The cells were both ovoid and spindle shaped, with a high mitotic rate. There was no extranodal spread. The cells were positive for S100, focally positive for HMB45, with only scattered cells positive for Melan A.

SUMMARY

"CONTENTS RIGHT AXILLA" - metastatic malignant melanoma in 1/33 nodes.

REPORTED BY: Dr.

Source: NCI Genomic Data Commons file da27f5b4-c12d-4848-b2d1-26d17f3f27ce (TCGA-EE-A2MS.26FFB127-64C5-41C3-9C9C-68A722B3CF66.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).